Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3562, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3562-01A (Primary Tumor).

Diagnosis:

Resected colon with a broad, ulcerated, moderately differentiated adenocarcinoma of colorectal type, with infiltration of the pericolic adipose tissue, lymphangiosis carcinomatosa with tumor and seven local lymph node metastases. Tumor-free colon resection margins. Tumor-free mesenteric resection margin. The remaining mucous membrane of the colon displaying a circumscribed, ulcerous defect with remains of a tubular adenoma with moderate epithelial dysplasia, as well as a further small tubular adenoma, likewise with moderate dysplasia (synonymously: mild intraepithelial neoplasia).

Stage of tumor: pT3, pN2 (7/28), MX; G2, L1, V0, local R0

Source: NCI Genomic Data Commons file 2205eb6d-137d-4dcd-8486-4ce996bac67d (TCGA-AA-3562.98738F18-85BD-4AA9-887D-443A1BC00694.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).